Somatic mutation profile of tumor specimen C3L-00907-01 (aliquot CPT0064370006) from CPTAC case C3L-00907, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.8 years (20,369 days).
Specimen C3L-00907-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2ebcfd7-bf61-49ea-b1f1-bc22714d7694.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00907-31 (Blood Derived Normal), aliquot CPT0065420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca20e40c-708d-43e1-a0b2-05eb71baf5bb

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 8, Intron 4, Splice Region 4, Splice Site 2, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM5C | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057518697, BM1323210, COSV100949576, COSV64762787; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 170/548 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs5030807, CM941368, COSV56543066, COSV56543312, COSV56543561; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs752916520, COSV68067373, COSV68069242; called by muse, mutect2, varscan2
- ADCY4 | c.931-4C>T | Splice Region (SNP) | VAF 34/127 reads (27%) | catalogued as rs1258704765; called by muse, mutect2, varscan2
- FOXF1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs1030195503; called by muse, mutect2, varscan2
- GRHPR | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 164/709 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs952908719; called by muse, mutect2, varscan2
- MEFV | c.1760-5C>T | Splice Region (SNP) | VAF 84/445 reads (19%) | catalogued as rs1319612887; called by muse, mutect2
- MTG1 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 78/308 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as rs559297659, COSV100448997; called by muse, mutect2, varscan2
- OR1C1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101376249; called by muse, mutect2, varscan2
- PAK6 | c.-116C>T | Splice Region (SNP) | VAF 61/249 reads (24%) | catalogued as rs1460458488; called by muse, mutect2, varscan2
- PCDHA7 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 197/1194 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs781943368; called by muse, mutect2, varscan2
- PPM1A | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs865808535; called by muse, varscan2
- PRM2 | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 128/464 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99617703; called by muse, mutect2, varscan2
- REPIN1 | c.1379T>C p.V460A | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.649); catalogued as rs770215207; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2237G>C p.R746T | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs780882235; called by muse, mutect2, varscan2
- ZNF513 | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV52008679; called by muse, mutect2, varscan2
- ABCC1 | c.1702T>A p.Y568N | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AMY2A | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- BHMG1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- BLZF1 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- DST | c.825A>C p.E275D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GLS | c.1492A>G p.M498V | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HDHD3 | c.346G>T p.G116W | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HELLS | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 97/525 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- HMCN2 | c.4541C>A p.P1514Q | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- IL10 | c.300C>G p.N100K | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- KRBA2 | c.1466_1467insTT p.L490Sfs*23 | Frame Shift Ins (INS) | VAF 4/50 reads (8%) | called by mutect2, pindel
- MAPK6 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MIOX | c.341-7_341-6insA | Splice Region (INS) | VAF 44/211 reads (21%) | called by mutect2, pindel, varscan2
- MTF2 | c.712_728+1del p.X238_splice | Splice Site (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- NRBP1 | c.1572_1574del p.T525del | In Frame Del (DEL) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- NUP214 | c.5596T>C p.S1866P | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.099); called by muse, mutect2
- PCYOX1 | c.773G>C p.C258S | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PGAP6 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIP5K1C | c.1971G>C p.Q657H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PITPNM2 | c.1941C>A p.D647E | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POGK | c.1643T>A p.L548Q | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SCGN | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 68/298 reads (23%) | called by muse, mutect2, varscan2
- SKIV2L | c.2084G>T p.G695V | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- SRGAP3 | c.801+1del p.X267_splice | Splice Site (DEL) | VAF 116/361 reads (32%) | called by mutect2, pindel, varscan2
- TMEM108 | c.1328C>G p.T443R | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- ZBTB49 | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZNF177 | c.481T>G p.S161A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- ZNF281 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 120/576 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BORA | c.118T>C p.L40= | Silent (SNP) | VAF 52/271 reads (19%) | called by muse, mutect2, varscan2
- CRIM1 | c.1773G>A p.K591= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as rs756989756; called by muse, mutect2, varscan2
- ECHDC3 | c.474T>G p.V158= | Silent (SNP) | VAF 101/404 reads (25%) | called by muse, mutect2, varscan2
- HAS1 | c.129G>C p.G43= | Silent (SNP) | VAF 123/631 reads (19%) | catalogued as rs975588969; called by muse, mutect2, varscan2
- HOXB1 | c.210G>A p.S70= | Silent (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2, varscan2
- JMJD1C | c.4197C>A p.I1399= | Silent (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- LUC7L | c.57G>A p.R19= | Silent (SNP) | VAF 62/258 reads (24%) | catalogued as rs972994693; called by muse, mutect2, varscan2
- RHPN1 | c.1915C>A p.R639= | Silent (SNP) | VAF 163/710 reads (23%) | catalogued as rs374961930; called by muse, mutect2, varscan2
- ARIH1 | c.912-26T>G | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as rs73150876; called by muse, mutect2
- GYS1 | c.*615T>C | 3'UTR (SNP) | VAF 30/494 reads (6%) | called by muse, mutect2
- KIF1B | c.2115+6209A>C | Intron (SNP) | VAF 127/455 reads (28%) | called by muse, mutect2, varscan2
- NXF5 | n.456A>G | RNA (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- RSAD1 | c.474+91_474+94del | Intron (DEL) | VAF 48/147 reads (33%) | catalogued as rs765772428; called by pindel, varscan2
